Somatic mutation profile of tumor specimen ALCH-B2PS-TTP1-A (aliquot ALCH-B2PS-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B2PS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 78.8 years (28,770 days).
Specimen ALCH-B2PS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0f7e451-c71f-40b8-8ebd-49e8fba5df8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2PS-NB1-A (Blood Derived Normal), aliquot ALCH-B2PS-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b41c841-726b-4ca8-8c12-c8c9bb691a03

The open-access MAF lists 394 somatic variants for this specimen: 253 protein-altering or splice-affecting, 97 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 215, Silent 97, Intron 21, Nonsense Mutation 20, RNA 10, Frame Shift Del 8, 5'UTR 7, Splice Site 4, 5'Flank 3, Splice Region 3, Frame Shift Ins 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 241/465 reads (52%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.245A>G p.E82G | Missense Mutation (SNP) | VAF 278/726 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960018, COSV67961061, COSV67962846; called by muse, mutect2, varscan2
- TP53 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 589/898 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.2152A>T p.T718S | Missense Mutation (SNP) | VAF 174/653 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as rs760660569, COSV54389664; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1976C>T p.T659I | Missense Mutation (SNP) | VAF 166/528 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.08); catalogued as COSV55001562; called by muse, mutect2, varscan2
- AKNA | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 42/474 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs771515179, COSV56313777; called by muse, mutect2
- ALDH1L1 | c.1291G>T p.V431L | Missense Mutation (SNP) | VAF 128/782 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs769006288, COSV56412829; called by muse, mutect2, varscan2
- AP5B1 | c.2093G>T p.R698L | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs745327454; called by muse, mutect2, varscan2
- APC2 | c.1172G>C p.R391P | Missense Mutation (SNP) | VAF 30/317 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs372652826; called by muse, mutect2
- APOB | c.11046G>T p.K3682N | Missense Mutation (SNP) | VAF 78/282 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51955207; called by muse, mutect2, varscan2
- ARID1A | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 38/65 reads (58%) | catalogued as COSV61375021, COSV61381862; called by muse, mutect2, varscan2
- ASPM | c.10193G>A p.R3398H | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.974); catalogued as rs372574057; called by muse, mutect2
- BEGAIN | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); catalogued as COSV62068908; called by muse, varscan2
- BMPER | c.350G>T p.S117I | Missense Mutation (SNP) | VAF 631/1179 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763479289; called by muse, mutect2, varscan2
- C6orf118 | c.514C>A p.R172S | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.569); catalogued as COSV100024854; called by muse, mutect2, varscan2
- CAPN6 | c.1810G>T p.D604Y | Missense Mutation (SNP) | VAF 203/287 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60698002; called by muse, mutect2, varscan2
- CDH26 | c.1531G>T p.E511* | Nonsense Mutation (SNP) | VAF 326/1117 reads (29%) | catalogued as COSV54845613; called by muse, mutect2, varscan2
- CDK9 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64723717; called by muse, mutect2, varscan2
- CECR2 | c.2917C>A p.Q973K (on ENST00000342247 / NM_001290047.2; = p.Q790K on NM_001290046.1) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99378207; called by muse, mutect2, varscan2
- CEP164 | c.3866C>T p.S1289L | Missense Mutation (SNP) | VAF 117/593 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs758693012; called by muse, mutect2, varscan2
- CFHR5 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 86/405 reads (21%) | catalogued as rs370810049; called by muse, mutect2, varscan2
- CLMP | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 103/283 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as rs1181851913; called by muse, mutect2, varscan2
- COX6C | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 57/213 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs370274113; called by muse, mutect2, varscan2
- DDX31 | c.2104C>A p.H702N | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.289); catalogued as COSV100936743; called by muse, mutect2, varscan2
- ERICH3 | c.4476G>T p.Q1492H | Missense Mutation (SNP) | VAF 203/474 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs372742954; called by muse, mutect2, varscan2
- FAT3 | c.13288C>A p.Q4430K | Missense Mutation (SNP) | VAF 86/505 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs1410345794, COSV53115152; called by mutect2, varscan2
- GOLGA6L2 | c.1660G>T p.A554S | Missense Mutation (SNP) | VAF 82/954 reads (9%) | SIFT deleterious, low confidence (0.02); catalogued as rs757173952, COSV61474866; called by muse, mutect2
- GRM8 | c.2630C>A p.P877Q | Missense Mutation (SNP) | VAF 152/1005 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV100286925; called by muse, mutect2, varscan2
- H2AC16 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 51/302 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV99044966; called by muse, mutect2, varscan2
- HNRNPA1 | c.974T>G p.F325C (on ENST00000340913 / NM_031157.4; = p.F273C on NM_002136.4) | Missense Mutation (SNP) | VAF 113/605 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as COSV52935540; called by muse, mutect2, varscan2
- IFNL1 | c.524G>C p.R175P | Missense Mutation (SNP) | VAF 90/336 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61317757; called by muse, mutect2, varscan2
- IGSF1 | c.3062G>T p.G1021V | Missense Mutation (SNP) | VAF 321/475 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100812164; called by muse, mutect2, varscan2
- IL1RAPL1 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as COSV100150070; called by muse, mutect2, varscan2
- ING2 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 162/345 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs541098829; called by muse, mutect2, varscan2
- JAKMIP1 | c.373del p.A125Pfs*9 | Frame Shift Del (DEL) | VAF 65/304 reads (21%) | catalogued as COSV99290012; called by mutect2, pindel, varscan2
- KDR | c.2987A>G p.Y996C | Missense Mutation (SNP) | VAF 374/1090 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs892780242; called by muse, mutect2, varscan2
- LILRA1 | c.432T>G p.H144Q | Missense Mutation (SNP) | VAF 61/310 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375761986; called by muse, mutect2, varscan2
- LIMCH1 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 22/786 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs925258645, COSV58300436; called by muse, mutect2
- LRRC4C | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 45/385 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375987229; called by muse, mutect2, varscan2
- LRRC4C | c.650C>A p.P217Q | Missense Mutation (SNP) | VAF 196/744 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as rs375080235, COSV99539146; called by muse, mutect2, varscan2
- MAPK4 | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV68543338; called by muse, mutect2, varscan2
- MTCL1 | c.2069G>T p.G690V (on ENST00000306329 / NM_001378206.1; = p.G330V on NM_015210.4) | Missense Mutation (SNP) | VAF 120/325 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs760065754, COSV60405280; called by muse, mutect2, varscan2
- MYH7B | c.5515C>G p.R1839G | Missense Mutation (SNP) | VAF 99/359 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV52678155; called by muse, mutect2, varscan2
- MYT1L | c.2399C>T p.A800V | Missense Mutation (SNP) | VAF 103/401 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as COSV67708063, COSV67734022; called by muse, mutect2, varscan2
- NAP1L3 | c.205A>G p.S69G | Missense Mutation (SNP) | VAF 192/280 reads (69%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.522); catalogued as rs775226866; called by muse, varscan2
- NPBWR1 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 36/387 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV100488085; called by muse, mutect2
- NRXN3 | c.1262G>T p.R421L (on ENST00000335750 / NM_001330195.2; = p.R48L on NM_004796.6) | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59728680; called by muse, mutect2, varscan2
- OLA1 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as rs1208428639; called by muse, mutect2, varscan2
- OR52L1 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 158/465 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); catalogued as COSV59989566; called by muse, mutect2, varscan2
- OR7D4 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 71/472 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV104394201, COSV58071395; called by muse, mutect2, varscan2
- OTOF | c.3015del p.T1006Pfs*20 (on ENST00000272371 / NM_194248.3; = p.T259Pfs*20 on NM_004802.4) | Frame Shift Del (DEL) | VAF 104/328 reads (32%) | catalogued as COSV55495078; called by mutect2, pindel, varscan2
- PCDHB9 | c.1176dup p.L393Sfs*6 | Frame Shift Ins (INS) | VAF 70/368 reads (19%) | catalogued as rs782200278; called by mutect2, varscan2
- PDGFRA | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 229/785 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57264474; called by muse, mutect2, varscan2
- PRB1 | c.248A>T p.Q83L | Missense Mutation (SNP) | VAF 81/378 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV53704275; called by muse, varscan2
- PRPF3 | c.1231T>C p.Y411H | Missense Mutation (SNP) | VAF 80/524 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.048); catalogued as COSV61395357; called by muse, varscan2
- PTH2R | c.1283G>A p.W428* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as COSV55913990; called by muse, varscan2
- PZP | c.1044C>A p.F348L | Missense Mutation (SNP) | VAF 57/283 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as rs762052052, COSV54354349; called by muse, mutect2, varscan2
- RBPJL | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 124/356 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs367850272; called by muse, mutect2, varscan2
- RNF227 | c.455G>C p.R152P | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1447400519; called by muse, mutect2
- RTP1 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56619660; called by muse, mutect2, varscan2
- SARS2 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs760018219, COSV55501634; called by muse, mutect2
- SART1 | c.841G>T p.V281L | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV56711281, COSV56712628; called by muse, mutect2, varscan2
- SEMA3D | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 87/500 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99406313; called by muse, mutect2, varscan2
- SLC13A3 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 110/473 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs751428434; called by muse, mutect2, varscan2
- SLC17A1 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 73/379 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs376055863; called by muse, mutect2, varscan2
- SLC4A1 | c.1940G>T p.G647V | Missense Mutation (SNP) | VAF 106/286 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as CD962156, COSV52263498; called by muse, mutect2, varscan2
- SLC7A7 | c.1443G>T p.R481S | Missense Mutation (SNP) | VAF 138/471 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.04); catalogued as rs748360606; called by muse, mutect2, varscan2
- SLC9A3R2 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as rs200328877; called by muse, mutect2, varscan2
- SMAD6 | c.1369G>C p.G457R | Missense Mutation (SNP) | VAF 118/308 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374661549; called by muse, mutect2, varscan2
- SNAP25 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 43/149 reads (29%) | catalogued as COSV99655116; called by muse, mutect2, varscan2
- SOX17 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 97/363 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.046); catalogued as COSV99810454; called by muse, mutect2, varscan2
- SPEG | c.8240G>T p.R2747L | Missense Mutation (SNP) | VAF 178/522 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56666009; called by muse, mutect2, varscan2
- SPTA1 | c.3192C>A p.Y1064* | Nonsense Mutation (SNP) | VAF 172/685 reads (25%) | catalogued as COSV100934111, COSV100934153; called by muse, mutect2, varscan2
- SRCAP | c.8870C>T p.A2957V | Missense Mutation (SNP) | VAF 52/313 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs1385294472; called by muse, mutect2, varscan2
- TEX15 | c.562G>T p.G188* (on ENST00000638951; = p.G184* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as rs1356487866, COSV73041917; called by mutect2, varscan2
- TRABD | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 147/516 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.938); catalogued as rs149826780; called by muse, mutect2, varscan2
- TRAM2 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs377045665; called by muse, mutect2, varscan2
- TRGV10 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 68/519 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as rs1045663060; called by muse, mutect2, varscan2
- VPS13B | c.2117T>C p.M706T | Missense Mutation (SNP) | VAF 106/334 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV62026324; called by muse, mutect2, varscan2
- ZEB2 | c.3187C>T p.R1063C | Missense Mutation (SNP) | VAF 103/642 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1301244969, COSV57959925; called by muse, mutect2, varscan2
- ZNF208 | c.2936del p.G979Afs*15 | Frame Shift Del (DEL) | VAF 142/453 reads (31%) | catalogued as COSV68104904; called by mutect2, pindel, varscan2
- ZRANB3 | c.3079G>A p.G1027R | Missense Mutation (SNP) | VAF 77/497 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs747084229, COSV51503969; called by muse, mutect2, varscan2
- ABCC6 | c.1033C>G p.P345A | Missense Mutation (SNP) | VAF 170/621 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, varscan2
- ABL2 | c.3506dup p.L1169Ffs*10 (on ENST00000502732 / NM_007314.4; = p.L1154Ffs*10 on NM_005158.5) | Frame Shift Ins (INS) | VAF 49/217 reads (23%) | called by mutect2, pindel, varscan2
- AC098582.1 | c.2101A>T p.N701Y | Missense Mutation (SNP) | VAF 225/811 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- ACACB | c.6826G>A p.E2276K | Missense Mutation (SNP) | VAF 197/457 reads (43%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM2 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ADCY3 | c.1535C>A p.A512D | Missense Mutation (SNP) | VAF 72/258 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- AL031777.2 | c.170A>G p.E57G | Missense Mutation (SNP) | VAF 150/464 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ALS2 | c.4211A>T p.N1404I | Missense Mutation (SNP) | VAF 124/779 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ANK2 | c.2765T>C p.M922T | Missense Mutation (SNP) | VAF 382/1297 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ANK2 | c.7228G>A p.E2410K | Missense Mutation (SNP) | VAF 41/318 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANO5 | c.2092C>A p.L698I | Missense Mutation (SNP) | VAF 128/507 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- APPL2 | c.1123A>G p.R375G | Missense Mutation (SNP) | VAF 138/408 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGAP11B | c.574A>T p.S192C | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ARHGAP31 | c.2439G>C p.L813F | Missense Mutation (SNP) | VAF 271/1288 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ARMCX1 | c.580T>A p.F194I | Missense Mutation (SNP) | VAF 120/169 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASTN1 | c.2726C>G p.T909R | Missense Mutation (SNP) | VAF 20/770 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- BAIAP3 | c.1218C>G p.H406Q | Missense Mutation (SNP) | VAF 76/521 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- BCAR1 | c.2141C>G p.P714R | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BFSP1 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4744G>T p.D1582Y | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BUB1 | c.1218-1G>C p.X406_splice | Splice Site (SNP) | VAF 50/265 reads (19%) | called by muse, mutect2, varscan2
- C1QTNF4 | c.839G>C p.R280P | Missense Mutation (SNP) | VAF 97/306 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CADPS2 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- CCDC39 | c.2268C>T p.S756= | Splice Region (SNP) | VAF 26/136 reads (19%) | called by muse, varscan2
- CCDC80 | c.2654C>A p.S885Y | Missense Mutation (SNP) | VAF 171/817 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCT8L2 | c.1597T>C p.W533R | Missense Mutation (SNP) | VAF 126/355 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP162 | c.294A>C p.L98F | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- CFAP65 | c.3553T>G p.S1185A | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CFAP73 | c.89C>A p.P30Q | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- CHAF1A | c.1714G>T p.G572C | Missense Mutation (SNP) | VAF 112/321 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD8 | c.2855G>T p.R952L (on ENST00000646647 / NM_001170629.2; = p.R673L on NM_020920.4) | Missense Mutation (SNP) | VAF 112/370 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CNGB1 | c.3698C>G p.P1233R | Missense Mutation (SNP) | VAF 75/360 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- COL11A1 | c.2434C>T p.P812S | Missense Mutation (SNP) | VAF 263/594 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL18A1 | c.2582G>T p.G861V (on ENST00000359759 / NM_130444.3; = p.G626V on NM_030582.4) | Missense Mutation (SNP) | VAF 195/425 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A6 | c.1631T>C p.L544P | Missense Mutation (SNP) | VAF 157/707 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CRYBB1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 178/537 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CRYL1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 103/204 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CSMD3 | c.8593G>T p.G2865C (on ENST00000297405 / NM_001363185.1; = p.G2696C on NM_052900.3) | Missense Mutation (SNP) | VAF 138/683 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNNA3 | c.436T>C p.C146R | Missense Mutation (SNP) | VAF 102/329 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUX2 | c.2239C>G p.Q747E | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DISP2 | c.3973C>A p.Q1325K | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLG2 | c.427A>T p.R143* | Nonsense Mutation (SNP) | VAF 54/376 reads (14%) | called by muse, mutect2, varscan2
- DMRTC2 | c.950del p.N317Tfs*50 | Frame Shift Del (DEL) | VAF 39/127 reads (31%) | called by mutect2, pindel, varscan2
- DNAH6 | c.4898G>A p.S1633N | Missense Mutation (SNP) | VAF 99/320 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- DNAH9 | c.2401G>T p.E801* | Nonsense Mutation (SNP) | VAF 215/336 reads (64%) | called by muse, mutect2, varscan2
- DNHD1 | c.13041T>G p.S4347R | Missense Mutation (SNP) | VAF 122/436 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DUSP22 | c.512C>A p.A171D | Missense Mutation (SNP) | VAF 72/700 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, varscan2
- DYNC2I1 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 110/574 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ELOVL2 | c.466A>G p.I156V | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- EPB41L3 | c.3044G>T p.S1015I | Missense Mutation (SNP) | VAF 103/370 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- EPB41L3 | c.910A>T p.K304* | Nonsense Mutation (SNP) | VAF 63/190 reads (33%) | called by muse, mutect2, varscan2
- EPHB4 | c.34T>A p.L12M | Missense Mutation (SNP) | VAF 133/359 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ERICH3 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 166/352 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ESPNL | c.1994C>G p.P665R | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM171B | c.2198C>A p.P733H | Missense Mutation (SNP) | VAF 137/398 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- FAT3 | c.7585G>T p.G2529W | Missense Mutation (SNP) | VAF 178/652 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT3 | c.7586G>T p.G2529V | Missense Mutation (SNP) | VAF 176/646 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FBXO2 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 228/439 reads (52%) | called by muse, mutect2, varscan2
- FHOD3 | c.960G>C p.V320= | Splice Region (SNP) | VAF 14/45 reads (31%) | called by mutect2, varscan2
- FNDC1 | c.3433del p.Q1145Sfs*96 | Frame Shift Del (DEL) | VAF 85/242 reads (35%) | called by mutect2, pindel, varscan2
- FUT9 | c.523A>T p.T175S | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- GABRA1 | c.1043G>T p.S348I | Missense Mutation (SNP) | VAF 260/670 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); called by muse, varscan2
- GHSR | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 233/1393 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLIM4 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 34/384 reads (9%) | called by muse, mutect2
- GPR89A | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 62/309 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM8 | c.2629C>T p.P877S | Missense Mutation (SNP) | VAF 150/1010 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- H2BC11 | c.321G>C p.L107F | Missense Mutation (SNP) | VAF 108/532 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HELB | c.1615C>G p.P539A | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLA-E | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 87/519 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- HRNR | c.1729G>T p.G577C | Missense Mutation (SNP) | VAF 408/1504 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, varscan2
- IFITM10 | c.638G>T p.C213F | Missense Mutation (SNP) | VAF 128/410 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- IGHG1 | c.794A>T p.E265V | Missense Mutation (SNP) | VAF 254/1068 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.284); called by muse, varscan2
- IGKV1-12 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 384/3010 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- IPO4 | c.70-8C>G | Splice Region (SNP) | VAF 61/246 reads (25%) | called by muse, mutect2, varscan2
- IQSEC3 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 50/718 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.934); called by muse, mutect2
- JHY | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 101/596 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- KCNMA1 | c.3566T>G p.L1189R (on ENST00000286628 / NM_001161352.2; = p.L1131R on NM_002247.4) | Missense Mutation (SNP) | VAF 325/788 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KMT2D | c.8275C>T p.P2759S | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KMT2D | c.7978G>T p.E2660* | Nonsense Mutation (SNP) | VAF 13/317 reads (4%) | called by muse, mutect2
- KREMEN1 | c.785G>T p.R262M (on ENST00000407188; = p.R264M on NM_032045.5) | Missense Mutation (SNP) | VAF 80/274 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.832); called by muse, mutect2
- KREMEN1 | c.786G>T p.R262S (on ENST00000407188; = p.R264S on NM_032045.5) | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.251); called by muse, mutect2
- KRTAP4-7 | c.54C>A p.D18E | Missense Mutation (SNP) | VAF 80/327 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2
- LTBP1 | c.4184C>T p.A1395V (on ENST00000404816 / NM_206943.4; = p.A1069V on NM_000627.4) | Missense Mutation (SNP) | VAF 119/416 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.134); called by muse, varscan2
- M1AP | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 276/832 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MAP4K3 | c.785C>G p.P262R | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARCO | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2
- MAST3 | c.2509G>T p.A837S | Missense Mutation (SNP) | VAF 155/453 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCM3AP | c.3428_3429del p.E1143Afs*10 | Frame Shift Del (DEL) | VAF 84/408 reads (21%) | called by pindel, varscan2
- MECOM | c.863C>T p.P288L (on ENST00000468789 / NM_001105078.4; = p.P476L on NM_004991.4) | Missense Mutation (SNP) | VAF 230/1436 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MMP16 | c.405-1G>T p.X135_splice | Splice Site (SNP) | VAF 29/127 reads (23%) | called by muse, mutect2, varscan2
- MPEG1 | c.1888T>A p.W630R | Missense Mutation (SNP) | VAF 181/408 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MPEG1 | c.1346G>A p.C449Y | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MROH1 | c.2998G>T p.G1000C | Missense Mutation (SNP) | VAF 181/717 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- MTG2 | c.62G>C p.W21S | Missense Mutation (SNP) | VAF 154/476 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MUC17 | c.3494T>C p.M1165T | Missense Mutation (SNP) | VAF 264/585 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCF4 | c.836A>T p.Q279L | Missense Mutation (SNP) | VAF 559/1131 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- NECAB1 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 118/439 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NETO2 | c.1363A>T p.S455C | Missense Mutation (SNP) | VAF 160/299 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, varscan2
- NFKBIZ | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- NOL4 | c.1879G>C p.A627P | Missense Mutation (SNP) | VAF 87/277 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOTCH1 | c.1773C>G p.C591W | Missense Mutation (SNP) | VAF 191/742 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPEPPS | c.1087G>C p.V363L | Missense Mutation (SNP) | VAF 89/320 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NUP85 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 82/1027 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR13C9 | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, varscan2
- OR1J4 | c.667del p.V223Sfs*50 | Frame Shift Del (DEL) | VAF 96/344 reads (28%) | called by mutect2, pindel, varscan2
- OR1S1 | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 79/486 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- OR2T1 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 108/318 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR51F2 | c.708G>T p.R236S | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- OR51I2 | c.238A>C p.T80P | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OTUD3 | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 228/511 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PACS2 | c.1388G>T p.R463L | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PARP11 | c.770_771del p.T257Ifs*15 | Frame Shift Del (DEL) | VAF 31/328 reads (9%) | called by pindel, varscan2
- PCDH11Y | c.410A>T p.H137L (on ENST00000400457 / NM_032973.2; = p.H126L on NM_032971.3) | Missense Mutation (SNP) | VAF 76/395 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PDZRN3 | c.2344G>T p.A782S | Missense Mutation (SNP) | VAF 126/241 reads (52%) | SIFT tolerated (0.64); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PEX5L | c.777C>G p.N259K | Missense Mutation (SNP) | VAF 90/1232 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2
- PGBD1 | c.1955A>G p.E652G | Missense Mutation (SNP) | VAF 174/528 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- PGM5 | c.1347C>G p.D449E | Missense Mutation (SNP) | VAF 179/628 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PKN1 | c.1121G>T p.S374I | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- POSTN | c.2300C>A p.T767N | Missense Mutation (SNP) | VAF 88/187 reads (47%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- POU5F1B | c.747C>G p.F249L | Missense Mutation (SNP) | VAF 405/1452 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- PTPN3 | c.1473G>T p.E491D | Missense Mutation (SNP) | VAF 141/320 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAX | c.181A>T p.K61* | Nonsense Mutation (SNP) | VAF 17/347 reads (5%) | called by muse, mutect2
- RBM7 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 61/350 reads (17%) | called by muse, mutect2, varscan2
- RIMS4 | c.59A>G p.Y20C | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- RNF122 | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2
- RP1 | c.5290T>A p.C1764S | Missense Mutation (SNP) | VAF 167/541 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- RPUSD4 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- RTL1 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 61/298 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RTN4RL1 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 60/894 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SELENBP1 | c.785C>G p.A262G | Missense Mutation (SNP) | VAF 107/386 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SEMA3C | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SERPINA3 | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 95/1049 reads (9%) | called by muse, mutect2
- SFMBT2 | c.1330+1G>T p.X444_splice | Splice Site (SNP) | VAF 71/167 reads (43%) | called by muse, mutect2, varscan2
- SH3D19 | c.695A>C p.D232A | Missense Mutation (SNP) | VAF 158/335 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- SIPA1L1 | c.3406G>T p.V1136F | Missense Mutation (SNP) | VAF 171/594 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SLAMF6 | c.260A>C p.N87T | Missense Mutation (SNP) | VAF 135/1026 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- SLIT3 | c.114T>A p.C38* | Nonsense Mutation (SNP) | VAF 110/207 reads (53%) | called by muse, mutect2, varscan2
- STAR | c.771C>A p.N257K | Missense Mutation (SNP) | VAF 267/1128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- STARD9 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.077); called by muse, varscan2
- SYT13 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- TBR1 | c.1546T>G p.Y516D | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCN1 | c.120G>T p.L40F | Missense Mutation (SNP) | VAF 204/612 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); called by muse, varscan2
- TLR8 | c.1867T>A p.L623M (on ENST00000218032 / NM_138636.5; = p.L641M on NM_016610.4) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- TMEM132C | c.591G>C p.E197D | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TMEM191B | c.440T>A p.L147Q | Missense Mutation (SNP) | VAF 64/487 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMEM191C | c.440T>A p.L147Q | Missense Mutation (SNP) | VAF 130/437 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRAF5 | c.467A>T p.H156L | Missense Mutation (SNP) | VAF 167/504 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TRAV21 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 57/826 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.299); called by muse, mutect2
- TRDN | c.1910C>A p.S637* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- TRGV1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 19/542 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- TRIB1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 129/404 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRIM51 | c.756A>T p.L252F | Missense Mutation (SNP) | VAF 207/651 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2
- TRPM1 | c.2410G>C p.E804Q | Missense Mutation (SNP) | VAF 171/819 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TRPM1 | c.2323C>G p.Q775E | Missense Mutation (SNP) | VAF 67/411 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TTN | c.46583A>G p.K15528R (on ENST00000591111; = p.K8104R on NM_003319.4) | Missense Mutation (SNP) | VAF 98/232 reads (42%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UAP1 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 43/327 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- UCP2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- UNC13C | c.2551G>T p.D851Y | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- UNC5D | c.1019G>C p.G340A | Missense Mutation (SNP) | VAF 83/429 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- UNC5D | c.1866C>A p.H622Q | Missense Mutation (SNP) | VAF 79/673 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VN1R5 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 168/663 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- WLS | c.1552C>A p.L518I | Missense Mutation (SNP) | VAF 30/560 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.967); called by muse, mutect2
- XIRP2 | c.8902C>A p.Q2968K (on ENST00000628543; = p.Q3143K on NM_152381.6) | Missense Mutation (SNP) | VAF 145/350 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- XKR9 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.091); called by muse, varscan2
- XPNPEP3 | c.969+2_969+4dup p.X323_splice | Splice Site (INS) | VAF 236/699 reads (34%) | called by mutect2, pindel, varscan2
- ZBTB10 | c.230T>A p.L77Q | Missense Mutation (SNP) | VAF 81/286 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ZNF350 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 184/508 reads (36%) | called by muse, mutect2, varscan2
- ZNF419 | c.991A>T p.M331L | Missense Mutation (SNP) | VAF 108/310 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF628 | c.2038G>T p.V680F | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ZNF649 | c.128A>G p.N43S | Missense Mutation (SNP) | VAF 169/904 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ZNF664 | c.769A>G p.K257E | Missense Mutation (SNP) | VAF 104/331 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ABCB1 | c.2166A>T p.G722= | Silent (SNP) | VAF 82/579 reads (14%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.168T>C p.P56= | Silent (SNP) | VAF 90/413 reads (22%) | called by muse, mutect2, varscan2
- ADGRA2 | c.948T>A p.S316= | Silent (SNP) | VAF 50/275 reads (18%) | called by muse, mutect2, varscan2
- ADM5 | c.222C>T p.P74= | Silent (SNP) | VAF 117/261 reads (45%) | called by muse, mutect2, varscan2
- AOC2 | c.1653G>T p.P551= | Silent (SNP) | VAF 107/362 reads (30%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.5907C>G p.S1969= | Silent (SNP) | VAF 24/74 reads (32%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.132C>T p.S44= | Silent (SNP) | VAF 107/245 reads (44%) | called by muse, mutect2, varscan2
- ASPG | c.1401C>T p.G467= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as rs1156311921, COSV101496331; called by muse, mutect2
- ATXN2L | c.1482A>T p.P494= | Silent (SNP) | VAF 129/579 reads (22%) | catalogued as rs747464513; called by muse, mutect2, varscan2
- BRCA2 | c.5427C>T p.C1809= | Silent (SNP) | VAF 32/266 reads (12%) | catalogued as rs80359791, COSV101204738; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- C10orf71 | c.4089G>A p.Q1363= | Silent (SNP) | VAF 107/224 reads (48%) | called by muse, mutect2, varscan2
- C1orf127 | c.1578A>G p.E526= | Silent (SNP) | VAF 114/261 reads (44%) | catalogued as rs780231005; called by muse, mutect2, varscan2
- C1orf87 | c.708C>T p.I236= | Silent (SNP) | VAF 125/248 reads (50%) | called by muse, mutect2, varscan2
- C3orf33 | c.378T>G p.T126= (on ENST00000340171 / NM_001308229.2; = p.T83= on NM_173657.2) | Silent (SNP) | VAF 78/183 reads (43%) | called by muse, mutect2, varscan2
- CAMTA1 | c.1767C>A p.I589= | Silent (SNP) | VAF 120/274 reads (44%) | catalogued as rs142209731; called by muse, mutect2, varscan2
- CARD6 | c.2607G>A p.Q869= | Silent (SNP) | VAF 14/404 reads (3%) | called by muse, mutect2
- CCDC197 | c.96C>T p.L32= | Silent (SNP) | VAF 157/459 reads (34%) | called by muse, mutect2, varscan2
- CDC42BPA | c.1917T>A p.A639= | Silent (SNP) | VAF 94/318 reads (30%) | called by muse, varscan2
- CDRT15L2 | c.546C>A p.G182= | Silent (SNP) | VAF 25/169 reads (15%) | called by muse, mutect2, varscan2
- CIC | c.3555C>A p.A1185= | Silent (SNP) | VAF 63/186 reads (34%) | called by muse, mutect2, varscan2
- CILP2 | c.2799G>T p.P933= | Silent (SNP) | VAF 141/415 reads (34%) | catalogued as COSV52274650; called by muse, mutect2, varscan2
- CNTNAP2 | c.3283C>A p.R1095= | Silent (SNP) | VAF 158/864 reads (18%) | catalogued as COSV100662227; called by muse, mutect2, varscan2
- CR1L | c.12C>G p.P4= | Silent (SNP) | VAF 109/319 reads (34%) | called by muse, mutect2, varscan2
- CSMD3 | c.6687G>T p.P2229= (on ENST00000297405 / NM_001363185.1; = p.P2125= on NM_052900.3) | Silent (SNP) | VAF 74/216 reads (34%) | catalogued as COSV52173617; called by muse, mutect2, varscan2
- CSMD3 | c.666A>C p.S222= | Silent (SNP) | VAF 178/596 reads (30%) | called by muse, mutect2, varscan2
- CSTF1 | c.1158C>T p.A386= | Silent (SNP) | VAF 169/642 reads (26%) | catalogued as rs377616855; called by muse, mutect2, varscan2
- DCHS2 | c.261C>A p.R87= | Silent (SNP) | VAF 127/287 reads (44%) | catalogued as COSV100251985; called by muse, mutect2, varscan2
- DDC | c.1134C>T p.I378= | Silent (SNP) | VAF 124/540 reads (23%) | catalogued as COSV63567771; called by muse, mutect2, varscan2
- DEPDC5 | c.2676G>T p.G892= (on ENST00000400246; = p.G961= on NM_014662.5) | Silent (SNP) | VAF 107/329 reads (33%) | called by muse, mutect2, varscan2
- EFCAB12 | c.1515C>T p.F505= | Silent (SNP) | VAF 16/535 reads (3%) | catalogued as COSV58178282; called by muse, mutect2
- EPHA5 | c.1779C>T p.L593= | Silent (SNP) | VAF 161/534 reads (30%) | catalogued as rs571143917; called by muse, mutect2, varscan2
- ESCO1 | c.1299G>A p.V433= | Silent (SNP) | VAF 100/293 reads (34%) | called by muse, mutect2, varscan2
- ETAA1 | c.1092A>G p.P364= | Silent (SNP) | VAF 81/261 reads (31%) | catalogued as rs370664974; called by muse, mutect2, varscan2
- FAM83E | c.969G>T p.A323= | Silent (SNP) | VAF 30/49 reads (61%) | catalogued as COSV52375337; called by muse, mutect2, varscan2
- FANCM | c.786G>T p.L262= | Silent (SNP) | VAF 116/467 reads (25%) | called by muse, mutect2, varscan2
- GATA3 | c.1197C>T p.H399= | Silent (SNP) | VAF 33/735 reads (4%) | catalogued as rs927749900, CD098943; called by muse, mutect2
- GOLGA6L2 | c.15C>A p.P5= | Silent (SNP) | VAF 76/361 reads (21%) | called by muse, mutect2, varscan2
- GOLGA8M | c.1392G>A p.E464= | Silent (SNP) | VAF 395/1252 reads (32%) | called by muse, mutect2, varscan2
- GRK3 | c.651T>C p.Y217= | Silent (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- HDAC9 | c.733C>A p.R245= | Silent (SNP) | VAF 359/714 reads (50%) | called by muse, mutect2, varscan2
- HOXB1 | c.799C>A p.R267= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV53317805, COSV53317930; called by muse, mutect2
- HP1BP3 | c.1074C>T p.T358= | Silent (SNP) | VAF 87/185 reads (47%) | called by muse, mutect2, varscan2
- INS-IGF2 | c.156C>T p.P52= | Silent (SNP) | VAF 80/288 reads (28%) | called by muse, mutect2, varscan2
- KCTD16 | c.1005C>A p.R335= | Silent (SNP) | VAF 179/379 reads (47%) | called by muse, mutect2, varscan2
- KMT2C | c.14379A>G p.K4793= | Silent (SNP) | VAF 41/342 reads (12%) | called by muse, mutect2, varscan2
- LATS2 | c.2904G>A p.K968= | Silent (SNP) | VAF 133/231 reads (58%) | catalogued as rs747084524; called by muse, mutect2, varscan2
- LHX2 | c.558G>T p.V186= | Silent (SNP) | VAF 108/282 reads (38%) | called by muse, mutect2, varscan2
- LRRC32 | c.852C>A p.P284= | Silent (SNP) | VAF 153/801 reads (19%) | called by muse, mutect2, varscan2
- LRRK2 | c.1641A>T p.L547= | Silent (SNP) | VAF 43/113 reads (38%) | called by muse, mutect2, varscan2
- MAP3K4 | c.2034G>A p.E678= | Silent (SNP) | VAF 56/420 reads (13%) | called by muse, mutect2, varscan2
- MARCHF4 | c.280C>A p.R94= | Silent (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- MED13 | c.4737T>A p.V1579= | Silent (SNP) | VAF 79/708 reads (11%) | called by muse, mutect2, varscan2
- MLLT1 | c.1044G>T p.R348= | Silent (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- MLPH | c.312T>C p.C104= | Silent (SNP) | VAF 256/573 reads (45%) | called by muse, mutect2, varscan2
- NAALADL1 | c.1392C>T p.S464= | Silent (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- NCAN | c.2301C>T p.P767= | Silent (SNP) | VAF 32/191 reads (17%) | called by muse, mutect2, varscan2
- NELL1 | c.1434T>C p.D478= | Silent (SNP) | VAF 138/400 reads (35%) | called by muse, mutect2, varscan2
- NELL2 | c.2352G>T p.G784= | Silent (SNP) | VAF 109/472 reads (23%) | called by muse, mutect2, varscan2
- NETO2 | c.1473C>T p.C491= | Silent (SNP) | VAF 195/425 reads (46%) | catalogued as rs141742429; called by muse, varscan2
- NIN | c.1191G>A p.K397= | Silent (SNP) | VAF 96/495 reads (19%) | called by muse, mutect2, varscan2
- NOXA1 | c.195G>A p.V65= | Silent (SNP) | VAF 148/398 reads (37%) | called by muse, mutect2, varscan2
- NTRK1 | c.1743G>A p.E581= | Silent (SNP) | VAF 194/719 reads (27%) | catalogued as rs138423540, COSV62324807; called by muse, mutect2, varscan2
- NUP188 | c.4377C>G p.L1459= | Silent (SNP) | VAF 31/576 reads (5%) | called by muse, mutect2
- OR13C9 | c.27G>T p.L9= | Silent (SNP) | VAF 62/309 reads (20%) | catalogued as rs1440070950, COSV52240623, COSV52241832; called by muse, varscan2
- OR2AG1 | c.549C>T p.H183= | Silent (SNP) | VAF 283/800 reads (35%) | catalogued as rs769215620; called by muse, mutect2, varscan2
- OR5H1 | c.426C>T p.I142= | Silent (SNP) | VAF 129/778 reads (17%) | catalogued as rs909799957, COSV63403467; called by muse, mutect2, varscan2
- OR6S1 | c.45C>T p.V15= | Silent (SNP) | VAF 40/121 reads (33%) | called by muse, mutect2, varscan2
- PLEKHG2 | c.1053G>C p.G351= | Silent (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2
- PXDNL | c.3297G>A p.P1099= | Silent (SNP) | VAF 133/432 reads (31%) | catalogued as rs1429276841; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2850A>T p.P950= | Silent (SNP) | VAF 102/246 reads (41%) | called by muse, mutect2, varscan2
- SERPINA7 | c.1239G>C p.T413= | Silent (SNP) | VAF 275/442 reads (62%) | catalogued as COSV59664916; called by muse, mutect2, varscan2
- SIPA1L1 | c.3405G>T p.T1135= | Silent (SNP) | VAF 168/582 reads (29%) | called by muse, mutect2, varscan2
- SLC38A3 | c.1059G>A p.L353= | Silent (SNP) | VAF 87/161 reads (54%) | called by muse, mutect2, varscan2
- SLC5A11 | c.130C>T p.L44= | Silent (SNP) | VAF 40/199 reads (20%) | called by muse, mutect2, varscan2
- SLITRK2 | c.1803G>T p.S601= | Silent (SNP) | VAF 143/219 reads (65%) | catalogued as COSV59423496; called by muse, mutect2, varscan2
- SPATA31D1 | c.285G>T p.L95= | Silent (SNP) | VAF 20/177 reads (11%) | catalogued as rs369571227; called by muse, mutect2, varscan2
- SPEG | c.6669C>A p.V2223= | Silent (SNP) | VAF 63/459 reads (14%) | called by muse, mutect2, varscan2
- SPEG | c.6670C>A p.R2224= | Silent (SNP) | VAF 65/462 reads (14%) | called by muse, mutect2, varscan2
- SRF | c.678C>T p.P226= | Silent (SNP) | VAF 254/669 reads (38%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.345C>T p.F115= | Silent (SNP) | VAF 57/175 reads (33%) | catalogued as COSV99682809; called by muse, mutect2, varscan2
- SYMPK | c.3588T>A p.P1196= | Silent (SNP) | VAF 183/419 reads (44%) | called by muse, mutect2, varscan2
- TIMD4 | c.840T>A p.P280= | Silent (SNP) | VAF 82/170 reads (48%) | called by muse, mutect2, varscan2
- TNC | c.3270C>T p.L1090= | Silent (SNP) | VAF 121/435 reads (28%) | called by muse, mutect2, varscan2
- TNNI3K | c.2244C>T p.C748= | Silent (SNP) | VAF 57/139 reads (41%) | catalogued as rs751728279; called by muse, mutect2, varscan2
- TTN | c.69447G>T p.L23149= (on ENST00000591111; = p.L15725= on NM_003319.4) | Silent (SNP) | VAF 51/134 reads (38%) | catalogued as rs1397817214; called by muse, mutect2, varscan2
- TYSND1 | c.951C>T p.T317= | Silent (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- UNC5C | c.1587C>A p.S529= | Silent (SNP) | VAF 82/272 reads (30%) | catalogued as COSV71658679; called by muse, varscan2
- USH2A | c.9438A>T p.L3146= | Silent (SNP) | VAF 145/504 reads (29%) | catalogued as COSV56377600; called by muse, mutect2, varscan2
- UTP20 | c.24C>T p.H8= | Silent (SNP) | VAF 64/402 reads (16%) | called by muse, mutect2, varscan2
- VPS13C | c.5709A>G p.V1903= (on ENST00000644861 / NM_020821.3; = p.V1860= on NM_017684.5) | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as rs958720349; called by muse, mutect2, varscan2
- VPS8 | c.1416T>G p.A472= (on ENST00000625842 / NM_001349294.1; = p.A470= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 136/831 reads (16%) | called by muse, mutect2, varscan2
- WDFY4 | c.8163C>T p.D2721= | Silent (SNP) | VAF 144/303 reads (48%) | catalogued as rs890842326, COSV55440239; called by muse, mutect2, varscan2
- XDH | c.2613C>G p.T871= | Silent (SNP) | VAF 212/730 reads (29%) | catalogued as rs1409554513, COSV65150417; called by muse, mutect2, varscan2
- ZIC2 | c.720C>G p.P240= | Silent (SNP) | VAF 254/626 reads (41%) | catalogued as rs564858875; called by muse, varscan2
- ZNF267 | c.1254C>G p.R418= | Silent (SNP) | VAF 66/176 reads (38%) | called by muse, mutect2, varscan2
- ZNF469 | c.8928C>T p.A2976= (on ENST00000437464; = p.A3004= on NM_001367624.2) | Silent (SNP) | VAF 139/267 reads (52%) | called by muse, mutect2, varscan2
- ZNF729 | c.2844C>G p.S948= | Silent (SNP) | VAF 96/448 reads (21%) | called by muse, mutect2, varscan2
- AC112721.1 | n.369G>A | RNA (SNP) | VAF 34/116 reads (29%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1291G>T | RNA (SNP) | VAF 178/464 reads (38%) | called by muse, mutect2, varscan2
- AC244258.1 | n.697G>T | RNA (SNP) | VAF 56/319 reads (18%) | called by muse, mutect2, varscan2
- ACTR3BP2 | n.862G>T | RNA (SNP) | VAF 108/465 reads (23%) | called by muse, mutect2, varscan2
- ADAM6 | n.1208C>A | RNA (SNP) | VAF 227/944 reads (24%) | called by muse, mutect2, varscan2
- AL137017.1 | n.332+2085C>A | Intron (SNP) | VAF 147/303 reads (49%) | called by muse, mutect2, varscan2
- AL139260.3 | c.37-638C>T | Intron (SNP) | VAF 22/659 reads (3%) | called by muse, mutect2
- AL355916.3 | c.420-3917C>A | Intron (SNP) | VAF 155/678 reads (23%) | called by muse, mutect2, varscan2
- ARG1 | c.58-24G>A | Intron (SNP) | VAF 65/343 reads (19%) | called by muse, mutect2, varscan2
- ATL3 | chr11:63671715 T>C | 5'Flank (SNP) | VAF 19/72 reads (26%) | catalogued as rs1361892094; called by muse, mutect2, varscan2
- BIN3 | c.57+12G>A | Intron (SNP) | VAF 144/328 reads (44%) | catalogued as rs773533363; called by muse, mutect2, varscan2
- BSPRY | c.-13C>G | 5'UTR (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- CAMKK2 | c.-162G>T | 5'UTR (SNP) | VAF 184/478 reads (38%) | catalogued as rs745699279; called by muse, mutect2, varscan2
- CLUHP11 | n.199G>T | RNA (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
- COBLL1 | c.155+3725A>C | Intron (SNP) | VAF 102/276 reads (37%) | called by muse, mutect2, varscan2
- COLEC11 | chr2:3594964 A>T | 5'Flank (SNP) | VAF 51/139 reads (37%) | called by muse, mutect2, varscan2
- DFFB | c.782+469C>A | Intron (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- DGKZ | c.934-115G>T | Intron (SNP) | VAF 30/179 reads (17%) | called by muse, mutect2, varscan2
- ELP2 | c.2077-34_2077-33del | Intron (DEL) | VAF 91/507 reads (18%) | called by pindel, varscan2
- ESRRG | c.56+15810C>A | Intron (SNP) | VAF 160/531 reads (30%) | catalogued as rs1270416497; called by muse, mutect2, varscan2
- GCNT2 | c.925+26922del | Intron (DEL) | VAF 142/614 reads (23%) | called by mutect2, pindel, varscan2
- GOLGA8S | chr15:23354819 ins A | 5'Flank (INS) | VAF 8/15 reads (53%) | called by mutect2, varscan2
- IGLL1 | c.-21G>T | 5'UTR (SNP) | VAF 74/128 reads (58%) | called by muse, varscan2
- IGLL1 | c.-22G>T | 5'UTR (SNP) | VAF 74/128 reads (58%) | called by muse, varscan2
- LARGE1 | c.*20A>C | 3'UTR (SNP) | VAF 202/733 reads (28%) | called by muse, mutect2, varscan2
- LINC00896 | n.755G>C | RNA (SNP) | VAF 102/291 reads (35%) | called by muse, mutect2, varscan2
- LINC01205 | n.113C>A | RNA (SNP) | VAF 68/294 reads (23%) | called by muse, mutect2, varscan2
- LUM | c.*15A>C | 3'UTR (SNP) | VAF 81/238 reads (34%) | called by muse, mutect2, varscan2
- MEIS3 | c.447+18C>T | Intron (SNP) | VAF 118/274 reads (43%) | catalogued as rs755185619; called by muse, mutect2, varscan2
- MTX1 | chr1:155216398 G>A | 3'Flank (SNP) | VAF 159/587 reads (27%) | called by muse, mutect2, varscan2
- NLE1 | c.18+24G>T | Intron (SNP) | VAF 82/141 reads (58%) | catalogued as rs1428263835; called by muse, mutect2, varscan2
- PHOX2B | c.242-113G>A | Intron (SNP) | VAF 215/740 reads (29%) | catalogued as rs982133709; called by muse, mutect2, varscan2
- PPFIA4 | c.-193G>T | 5'UTR (SNP) | VAF 106/305 reads (35%) | called by muse, mutect2, varscan2
- PPP1R21 | c.1226-415A>G | Intron (SNP) | VAF 148/563 reads (26%) | called by muse, mutect2, varscan2
- RASA4DP | n.931del | RNA (DEL) | VAF 67/598 reads (11%) | called by mutect2, pindel, varscan2
- SCART1 | c.-11G>C | 5'UTR (SNP) | VAF 92/187 reads (49%) | called by muse, mutect2, varscan2
- SEPTIN5 | c.44-59C>T | Intron (SNP) | VAF 105/316 reads (33%) | called by muse, mutect2, varscan2
- SSH1 | c.1893+23G>T | Intron (SNP) | VAF 18/368 reads (5%) | called by muse, mutect2
- SYP | c.*4+11G>C | Intron (SNP) | VAF 180/299 reads (60%) | called by muse, mutect2, varscan2
- TRBV4-1 | c.-18C>G | 5'UTR (SNP) | VAF 164/433 reads (38%) | called by muse, mutect2, varscan2
- TRIM67 | c.1045-11211G>T | Intron (SNP) | VAF 138/440 reads (31%) | catalogued as COSV64158680; called by muse, varscan2
- TSR1 | c.1903+212G>A | Intron (SNP) | VAF 36/409 reads (9%) | called by muse, mutect2
- TTC41P | n.3039G>A | RNA (SNP) | VAF 49/219 reads (22%) | catalogued as rs1244264446; called by muse, mutect2, varscan2
- USH1C | c.1285-3930G>A | Intron (SNP) | VAF 105/1072 reads (10%) | catalogued as rs762549947; called by muse, mutect2, varscan2
